CPTAC case C3N-02700 — Lip — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Lip. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8b0ad21d-929d-446c-be13-fde7d97ab4b5

Demographics
Sex at birth: female; Race: white; Year of birth: 1936; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lip, NOS; Site of resection or biopsy: Lip, NOS; Age at diagnosis: 80.8 years (29,529 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 5 days; Progression or recurrence: no; Days to last follow up: 5 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 6.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 5 days; Disease response: Complete Response.
- Days to follow up: 5 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 68 kg; Height: 165 cm; BMI: 24.98.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02700-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 150 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02700-21: Section location: Lip; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3N-02700-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02700-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
